Surgical pathology report (de-identified scan), TCGA case TCGA-14-0786, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0786-01B (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

TISSUE SOURCE:

Part 1: Right temporal brain lesion, FS.
Part 2: Thrombosed vein.
Part 3: Right temporal brain tumor.

TCGA-14-0786

CLINICAL DIAGNOSIS & HISTORY:

Name of operation: Craniotomy for brain tumor.
Pre-Operative Diagnosis:
Brain tumor temporal lobe.
Post-Operative Diagnosis: { No Information Provided }

INTRAOPERATIVE CONSULTATION:

FS1A: RIGHT TEMPORAL BRAIN LESION (FROZEN SECTION): GLIOBLASTOMA
MULTIFORME.

The pathologist has reviewed and interpreted the case with the
fellow/resident.

[REDACTED]

GROSS DESCRIPTION:

Received are three specimens. Each is labeled with the
patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation
and designated as "right temporal brain lesion". The specimen
consists of multiple irregular fragments of pink-tan soft tissue
with admixed blood which range from 0.4 to 1.2 cm in greatest
diameter. An intraoperative consultation with frozen section is
performed with the remainder of the cryoblock submitted in
cassette "FS1A". The remainder of the tissue is submitted in
its entirety in cassette "1B".

Specimen #2 is received in formalin and designated as
"thrombosed vein and in tumor". The specimen consists of an
irregular fragment of tan to brown-red soft tissue which
measures 1.2 x 0.7 x 0.3 cm in greatest diameter. A 1.0 cm
length of blood vessel is seen with an average diameter of 0.2

[page 2 of 3]
GROSS DESCRIPTION (continued):

cm. The specimen is submitted in a single cassette wrapped in lens paper in cassette "2A".

Specimen #3 is received in formalin and designated as "right temporal brain tumor". The specimen consists of an irregular fragment of pink-tan soft tissue with focal areas of apparent necrosis. The specimen measures 2.9 x 2.7 x 1.4 cm. The specimen is serially sectioned and submitted in its entirety in cassettes "3A" through "3C".

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

The pathologist has reviewed and interpreted the case with the fellow/resident.

IMMUNOHISTOCHEMISTRY

INTERPRETATION:

BRAIN, RIGHT TEMPORAL TUMOR (EXCISION): GLIOBLASTOMA
MULTIFORME.

INTENSITY OF IMMUNOSTAIN (% POSITIVE)

	GLIOBLASTOMA MULTIFORME	RESULT
MIB-1	27% (mean 12%)	High proliferative activity

[page 3 of 3]
[REDACTED]

IMMUNOHISTOCHEMISTRY (continued) [REDACTED]

[REDACTED] [REDACTED]

DIAGNOSIS

BRAIN, RIGHT TEMPORAL LESION (EXCISION, FROZEN SECTION):
GLIOBLASTOMA MULTIFORME. (SEE COMMENT)

BRAIN, THROMBOSED VEIN (EXCISION): GLIOBLASTOMA MULTIFORME
WITH THROMBOSED BLOOD VESSEL.

BRAIN, RIGHT TEMPORAL TUMOR (EXCISION): GLIOBLASTOMA MULTIFORME.

COMMENT:

A MIB-1 is ordered on block 1B, and the results will be
issued as an addendum.

[REDACTED]

Tissue Committee Code: 1

[REDACTED]

ICD9 Codes:

1. 191.9 MALIG NEO BRAIN NOS

[REDACTED]

Source: NCI Genomic Data Commons file 45034835-ac19-4ff5-b64c-5949fc960c5b (TCGA-14-0786.4D0EB577-3E97-42F2-B830-5AD1D17C24B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).